Somatic mutation profile of cancer-model specimen HCM-WCMC-0785-C67-85A (3D Organoid, passage 12; aliquot HCM-WCMC-0785-C67-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-WCMC-0785-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 57.3 years (20,930 days).
Specimen HCM-WCMC-0785-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 228d0e0b-ca24-436c-a591-aa03b57a8a89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0785-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-0785-C67-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40bf2f9c-8799-4797-83ff-4ce347d699db

The open-access MAF lists 85 somatic variants for this specimen: 66 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 18, Nonsense Mutation 4, Frame Shift Del 2, Intron 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4726G>T p.E1576* | Nonsense Mutation (SNP) | VAF 141/443 reads (32%) | catalogued as rs1554086134, COSV57334276, COSV57398676; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 333/333 reads (100%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 300/578 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs368440679; called by muse, mutect2, varscan2
- AKT1 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV62573189; called by muse, mutect2
- CAPS2 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 79/266 reads (30%) | catalogued as COSV100158417; called by muse, mutect2, varscan2
- COL5A1 | c.1819G>A p.G607R | Missense Mutation (SNP) | VAF 167/539 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65675539; called by muse, mutect2, varscan2
- CRISPLD2 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 144/492 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1203552951; called by muse, mutect2, varscan2
- DDX41 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 328/538 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs760338178, COSV57252879; called by muse, mutect2, varscan2
- ETV1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 159/595 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.107); catalogued as rs186330943, COSV54145283, COSV99063377; called by muse, mutect2, varscan2
- FOXS1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 604/1182 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1197671466; called by muse, mutect2, varscan2
- GH2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 429/865 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs773623624, COSV60426741; called by muse, mutect2, varscan2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 174/410 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- KDM4D | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 159/349 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs782555584; called by muse, mutect2, varscan2
- MICAL2 | c.2978C>T p.P993L | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs370539217, COSV56323451, COSV56325483; called by muse, mutect2, varscan2
- NALCN | c.4118C>G p.S1373C | Missense Mutation (SNP) | VAF 198/340 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV51925859, COSV51928696; called by muse, mutect2, varscan2
- NRXN3 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 187/433 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs183291562; called by muse, mutect2, varscan2
- OR6F1 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 206/449 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs186143987, COSV57467500; called by muse, varscan2
- OR6N1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 149/587 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376841145; called by muse, mutect2, varscan2
- PCDH7 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 38/547 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.384); catalogued as rs770924379; called by muse, mutect2
- PDE1A | c.329del p.K110Rfs*43 | Frame Shift Del (DEL) | VAF 170/562 reads (30%) | catalogued as rs1559238050; called by mutect2, pindel, varscan2
- PKHD1 | c.3452C>T p.P1151L | Missense Mutation (SNP) | VAF 192/600 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs574099162, COSV61872779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEF | c.2190del p.F731Sfs*13 | Frame Shift Del (DEL) | VAF 277/946 reads (29%) | catalogued as COSV100664480; called by mutect2, varscan2
- RNF175 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 205/399 reads (51%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1305884947; called by muse, mutect2, varscan2
- SLC4A11 | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 190/714 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538658493, CM074560; called by muse, mutect2, varscan2
- SYNE1 | c.707G>A p.R236Q (on ENST00000367255 / NM_182961.4; = p.R243Q on NM_033071.3) | Missense Mutation (SNP) | VAF 193/621 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs200704755, COSV55056838; called by muse, mutect2, varscan2
- TMEM132C | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 205/609 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs922523578, COSV59416644, COSV59428604; called by muse, mutect2, varscan2
- TNC | c.6149G>A p.R2050H | Missense Mutation (SNP) | VAF 149/478 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs370664222; called by muse, mutect2, varscan2
- TTLL4 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 190/608 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375574702, COSV99293899; called by muse, mutect2, varscan2
- WDR5 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 143/481 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs1333703664; called by muse, mutect2, varscan2
- ADAMTS20 | c.4614A>C p.R1538S | Missense Mutation (SNP) | VAF 128/513 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ADGRV1 | c.9488T>C p.M3163T | Missense Mutation (SNP) | VAF 214/331 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ALDH1L1 | c.2140T>C p.F714L | Missense Mutation (SNP) | VAF 20/385 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCDC166 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 294/619 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CCNK | c.854_856dup p.V285_P286insL | In Frame Ins (INS) | VAF 240/530 reads (45%) | called by mutect2, pindel, varscan2
- COL19A1 | c.1142C>T p.T381I | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMN2 | c.4691A>G p.D1564G | Missense Mutation (SNP) | VAF 121/602 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FN1 | c.2745T>A p.F915L | Missense Mutation (SNP) | VAF 165/499 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FUT6 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 40/696 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2
- GEM | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 168/345 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSD11B2 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 460/743 reads (62%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KCNK2 | c.107C>A p.S36* (on ENST00000444842 / NM_001017425.3; = p.S21* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 137/512 reads (27%) | called by muse, mutect2, varscan2
- KLHL32 | c.1160G>A p.C387Y | Missense Mutation (SNP) | VAF 172/555 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- KRTAP21-1 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 285/600 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- LAG3 | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 248/481 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.133); called by muse, varscan2
- MAN2B2 | c.163A>T p.N55Y | Missense Mutation (SNP) | VAF 104/237 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR7C2 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 291/444 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ORC5 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, varscan2
- PRAMEF15 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 261/1486 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRAMEF18 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 149/1111 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PROM1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 150/326 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- PRRC2C | c.4934T>G p.V1645G (on ENST00000367742; = p.V1643G on NM_015172.4) | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- RAB24 | c.287T>C p.F96S | Missense Mutation (SNP) | VAF 188/610 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RNF168 | c.434A>T p.Y145F | Missense Mutation (SNP) | VAF 229/446 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SELPLG | c.380_409del p.A127_P136del | In Frame Del (DEL) | VAF 102/641 reads (16%) | called by mutect2, varscan2
- SIRPB1 | c.684G>C p.E228D | Missense Mutation (SNP) | VAF 26/1070 reads (2%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); called by muse, mutect2
- SLC7A14 | c.1864C>A p.P622T | Missense Mutation (SNP) | VAF 174/418 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TAAR6 | c.1034T>C p.I345T | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TERB1 | c.471T>G p.I157M | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TNC | c.510A>C p.E170D | Missense Mutation (SNP) | VAF 148/556 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRPC1 | c.614A>T p.D205V (on ENST00000476941 / NM_001251845.2; = p.D171V on NM_003304.4) | Missense Mutation (SNP) | VAF 128/271 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB38 | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 153/304 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZC3H12D | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 115/421 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H13 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 130/450 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ZNF215 | c.155G>T p.R52I | Missense Mutation (SNP) | VAF 382/382 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF516 | c.2904C>G p.H968Q | Missense Mutation (SNP) | VAF 392/392 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF829 | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 87/474 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AACS | c.1317C>T p.T439= | Silent (SNP) | VAF 109/371 reads (29%) | catalogued as rs376926717, COSV99907999; called by muse, mutect2, varscan2
- APLP1 | c.1785C>A p.S595= (on ENST00000221891 / NM_001024807.3; = p.S594= on NM_005166.4) | Silent (SNP) | VAF 216/1073 reads (20%) | catalogued as COSV99697877; called by muse, mutect2, varscan2
- DDX25 | c.195A>G p.S65= | Silent (SNP) | VAF 205/205 reads (100%) | called by muse, mutect2, varscan2
- FREM2 | c.2103G>A p.P701= | Silent (SNP) | VAF 162/565 reads (29%) | catalogued as rs117758105, COSV99750967; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GJB3 | c.498C>T p.N166= | Silent (SNP) | VAF 162/624 reads (26%) | catalogued as rs750075235; called by muse, mutect2, varscan2
- GRIN2A | c.306C>T p.D102= | Silent (SNP) | VAF 222/693 reads (32%) | catalogued as rs200850130; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- HOXC8 | c.525A>G p.T175= | Silent (SNP) | VAF 325/519 reads (63%) | called by muse, mutect2, varscan2
- IKZF1 | c.427C>A p.R143= | Silent (SNP) | VAF 73/390 reads (19%) | catalogued as COSV58785753; called by muse, mutect2, varscan2
- IRX1 | c.348T>C p.A116= | Silent (SNP) | VAF 240/1197 reads (20%) | catalogued as COSV57358402, COSV57358593, COSV57363094; called by muse, mutect2, varscan2
- KCNH6 | c.2577C>T p.H859= | Silent (SNP) | VAF 203/918 reads (22%) | catalogued as rs547568764; called by muse, mutect2, varscan2
- MIDEAS | c.2109A>T p.V703= | Silent (SNP) | VAF 20/422 reads (5%) | called by muse, mutect2
- NID1 | c.555C>T p.S185= | Silent (SNP) | VAF 235/526 reads (45%) | called by muse, mutect2, varscan2
- SCUBE2 | c.1920C>T p.D640= | Silent (SNP) | VAF 130/368 reads (35%) | catalogued as rs377361912; called by muse, mutect2, varscan2
- SLC36A1 | c.1266C>T p.T422= | Silent (SNP) | VAF 506/790 reads (64%) | catalogued as rs1232994628; called by muse, mutect2, varscan2
- SLC4A2 | c.2907G>A p.S969= | Silent (SNP) | VAF 167/517 reads (32%) | catalogued as rs17852574, COSV52539407; called by muse, mutect2, varscan2
- SPEM2 | c.1308G>A p.A436= | Silent (SNP) | VAF 457/458 reads (100%) | catalogued as rs770047620; called by muse, mutect2, varscan2
- TRIM71 | c.501C>T p.L167= | Silent (SNP) | VAF 202/436 reads (46%) | catalogued as rs1188933657; called by muse, mutect2, varscan2
- ZNF8 | c.1200C>T p.N400= | Silent (SNP) | VAF 223/1052 reads (21%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+36058A>C | Intron (SNP) | VAF 150/375 reads (40%) | called by muse, mutect2, varscan2
